Somatic mutation profile of tumor specimen 0DXJH0 from CCDI case PBCRDA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Eye, NOS; Age at diagnosis: 11.6 years (4,243 days).
Specimen 0DXJH0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 265f43af-4602-4c57-9d5d-164ed646e54d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DXJEF (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/43e91f03-03f2-48c8-b607-3432fcf49c2b

The open-access MAF lists 76 somatic variants for this specimen: 47 protein-altering or splice-affecting, 15 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 15, Intron 8, 3'UTR 4, Nonsense Mutation 2, Splice Region 1, Frame Shift Ins 1, RNA 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMOT | c.1955T>C p.V652A (on ENST00000371959 / NM_001113490.1; = p.V243A on NM_133265.3) | Missense Mutation (SNP) | VAF 169/706 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs1354372989; called by muse, varscan2
- ATP6V1D | c.27C>G p.I9M | Missense Mutation (SNP) | VAF 101/536 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as rs960972603; called by muse, varscan2
- B3GAT2 | c.621G>A p.W207* | Nonsense Mutation (SNP) | VAF 232/746 reads (31%) | catalogued as rs943853919; called by muse, varscan2
- BCAS3 | c.238C>T p.H80Y | Missense Mutation (SNP) | VAF 76/344 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.029); catalogued as COSV101175025; called by muse, varscan2
- CAVIN2 | c.598G>A p.V200M | Missense Mutation (SNP) | VAF 245/1365 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs745440132; called by muse, varscan2
- CFAP61 | c.2408C>T p.T803M | Missense Mutation (SNP) | VAF 764/1348 reads (57%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.917); catalogued as rs780255308, COSV55619741, COSV55624296; called by muse, varscan2
- GREB1 | c.3120G>A p.P1040= | Splice Region (SNP) | VAF 82/560 reads (15%) | catalogued as rs762653939; called by muse, varscan2
- HCRTR2 | c.950A>G p.Y317C | Missense Mutation (SNP) | VAF 186/684 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.856); catalogued as rs769653153; called by muse, varscan2
- HNRNPUL2 | c.252G>C p.E84D | Missense Mutation (SNP) | VAF 78/362 reads (22%) | SIFT tolerated (0.46); PolyPhen benign (0.019); catalogued as rs747143789; called by muse, varscan2
- IL2RG | c.853C>T p.R285W | Missense Mutation (SNP) | VAF 324/826 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs762171617, COSV99340315; called by muse, varscan2
- KIF23 | c.1522C>T p.R508* | Nonsense Mutation (SNP) | VAF 214/914 reads (23%) | catalogued as rs888573274, COSV52977962; called by muse, varscan2
- KMT2B | c.659G>A p.R220Q | Missense Mutation (SNP) | VAF 83/510 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.921); catalogued as rs369563501; called by muse, varscan2
- LMF2 | c.1384G>A p.G462S | Missense Mutation (SNP) | VAF 156/631 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as COSV53316213; called by muse, varscan2
- LRRC8C | c.1063C>T p.R355C | Missense Mutation (SNP) | VAF 276/1175 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747378312, COSV64996016; called by muse, varscan2
- LVRN | c.545C>T p.A182V | Missense Mutation (SNP) | VAF 120/398 reads (30%) | SIFT tolerated (0.54); PolyPhen benign (0.153); catalogued as COSV100773770; called by muse, varscan2
- MOSPD2 | c.140T>A p.V47D | Missense Mutation (SNP) | VAF 252/1269 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV100996961; called by muse, varscan2
- NRK | c.172G>C p.A58P | Missense Mutation (SNP) | VAF 435/912 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV54599383; called by muse, varscan2
- TTN | c.43087G>C p.E14363Q (on ENST00000591111; = p.E6939Q on NM_003319.4) | Missense Mutation (SNP) | VAF 195/1182 reads (16%) | PolyPhen benign (0.346); catalogued as rs1305953554; called by muse, varscan2
- VCX3B | c.208G>A p.G70R | Missense Mutation (SNP) | VAF 104/1284 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.183); catalogued as rs774690483; called by muse, varscan2
- ACOT2 | c.428T>G p.L143R | Missense Mutation (SNP) | VAF 67/350 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, varscan2
- ADCY8 | c.3598G>C p.V1200L | Missense Mutation (SNP) | VAF 141/718 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.031); called by muse, varscan2
- ANTXRL | c.1072G>T p.V358L | Missense Mutation (SNP) | VAF 193/423 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, varscan2
- CIC | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 185/1142 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- CLGN | c.948T>G p.D316E | Missense Mutation (SNP) | VAF 234/1080 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.393); called by muse, varscan2
- COL5A3 | c.299C>A p.P100Q | Missense Mutation (SNP) | VAF 154/1049 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.015); called by muse, varscan2
- DNAJC1 | c.257G>C p.R86P | Missense Mutation (SNP) | VAF 178/755 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- HCN1 | c.444A>G p.I148M | Missense Mutation (SNP) | VAF 188/895 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.219); called by muse, varscan2
- IL15 | c.382G>A p.V128I | Missense Mutation (SNP) | VAF 391/1046 reads (37%) | SIFT tolerated (0.85); PolyPhen benign (0); called by muse, varscan2
- IRAK3 | c.1352A>G p.Y451C | Missense Mutation (SNP) | VAF 436/1490 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.818); called by muse, varscan2
- LRP1B | c.2068G>A p.V690M | Missense Mutation (SNP) | VAF 683/1205 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, varscan2
- LRP6 | c.110C>G p.T37R | Missense Mutation (SNP) | VAF 326/2154 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.024); called by muse, varscan2
- MTMR14 | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 142/612 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, varscan2
- NLRP2 | c.929A>G p.K310R | Missense Mutation (SNP) | VAF 158/586 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.226); called by muse, varscan2
- ORM2 | c.594G>C p.E198D | Missense Mutation (SNP) | VAF 104/582 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.011); called by muse, varscan2
- PEAR1 | c.2045G>T p.C682F | Missense Mutation (SNP) | VAF 356/476 reads (75%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, varscan2
- PNISR | c.727dup p.M243Nfs*4 | Frame Shift Ins (INS) | VAF 248/1000 reads (25%) | called by pindel, varscan2
- RFXANK | c.667G>T p.G223C | Missense Mutation (SNP) | VAF 124/847 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- SLC25A4 | c.616A>C p.K206Q | Missense Mutation (SNP) | VAF 239/1018 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.012); called by muse, varscan2
- SMARCA5 | c.2017G>C p.D673H | Missense Mutation (SNP) | VAF 277/1325 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, varscan2
- SYNE1 | c.7426C>T p.H2476Y (on ENST00000367255 / NM_182961.4; = p.H2483Y on NM_033071.3) | Missense Mutation (SNP) | VAF 254/910 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.005); called by muse, varscan2
- TMEM121 | c.889C>T p.P297S | Missense Mutation (SNP) | VAF 88/424 reads (21%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0.058); called by muse, varscan2
- ULK4 | c.3345G>T p.L1115F | Missense Mutation (SNP) | VAF 479/1079 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, varscan2
- USH2A | c.475C>A p.Q159K | Missense Mutation (SNP) | VAF 228/922 reads (25%) | SIFT tolerated (0.54); PolyPhen benign (0.015); called by muse, varscan2
- UTRN | c.586C>T p.L196F | Missense Mutation (SNP) | VAF 424/766 reads (55%) | SIFT deleterious (0.04); PolyPhen benign (0.031); called by muse, varscan2
- WDR17 | c.418G>T p.D140Y | Missense Mutation (SNP) | VAF 201/929 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, varscan2
- WDR19 | c.909G>C p.L303F | Missense Mutation (SNP) | VAF 108/574 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); called by muse, varscan2
- ZNF441 | c.1558A>G p.R520G | Missense Mutation (SNP) | VAF 222/1498 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.255); called by muse, varscan2
- CCDC39 | c.2079C>T p.Y693= | Silent (SNP) | VAF 248/1076 reads (23%) | catalogued as rs376782159; ClinVar: uncertain significance / likely benign; called by muse, varscan2
- CDH3 | c.1110C>T p.G370= | Silent (SNP) | VAF 101/504 reads (20%) | catalogued as rs566716627; called by muse, varscan2
- CRLS1 | c.9C>G p.A3= | Silent (SNP) | VAF 74/383 reads (19%) | called by muse, varscan2
- FREM2 | c.2559C>T p.H853= | Silent (SNP) | VAF 177/507 reads (35%) | catalogued as rs779617548, COSV99749716; ClinVar: likely benign; called by muse, varscan2
- GAB1 | c.633A>G p.T211= | Silent (SNP) | VAF 208/912 reads (23%) | called by muse, varscan2
- GRIK2 | c.1441A>C p.R481= | Silent (SNP) | VAF 300/1054 reads (28%) | called by muse, varscan2
- HTATSF1 | c.2172G>A p.R724= | Silent (SNP) | VAF 169/822 reads (21%) | called by muse, varscan2
- KCNC2 | c.588G>A p.A196= | Silent (SNP) | VAF 108/690 reads (16%) | called by muse, varscan2
- KRTAP19-2 | c.150C>G p.G50= | Silent (SNP) | VAF 222/887 reads (25%) | called by muse, varscan2
- MAFG | c.252G>A p.A84= | Silent (SNP) | VAF 142/422 reads (34%) | catalogued as rs770074111; called by muse, varscan2
- MUC5AC | c.2511C>A p.P837= | Silent (SNP) | VAF 214/434 reads (49%) | called by muse, varscan2
- PLEKHG6 | c.2358C>T p.S786= | Silent (SNP) | VAF 61/422 reads (14%) | catalogued as rs754245266; called by muse, varscan2
- SIX4 | c.1800G>A p.S600= | Silent (SNP) | VAF 138/642 reads (21%) | catalogued as COSV53670757; called by muse, varscan2
- TSPAN12 | c.663G>A p.Q221= | Silent (SNP) | VAF 261/1376 reads (19%) | called by muse, varscan2
- VSIG8 | c.1122G>A p.A374= | Silent (SNP) | VAF 44/191 reads (23%) | catalogued as rs985781493; called by muse, varscan2
- CLEC16A | c.2641+47G>T | Intron (SNP) | VAF 88/375 reads (23%) | called by muse, varscan2
- DENND1C | c.1584-14C>G | Intron (SNP) | VAF 194/444 reads (44%) | called by muse, varscan2
- FAM120C | c.*92A>G | 3'UTR (SNP) | VAF 32/122 reads (26%) | called by muse, varscan2
- FCAMR | c.1455-71G>A | Intron (SNP) | VAF 80/278 reads (29%) | called by muse, varscan2
- GP2 | c.-19A>C | 5'UTR (SNP) | VAF 40/196 reads (20%) | called by muse, varscan2
- IL10RA | c.689-46G>A | Intron (SNP) | VAF 24/140 reads (17%) | catalogued as rs1284613855, COSV57140842; called by muse, varscan2
- PPT2 | c.*17C>T | 3'UTR (SNP) | VAF 206/339 reads (61%) | catalogued as rs762955500; called by muse, varscan2
- PROSER3 | c.109-86G>C | Intron (SNP) | VAF 28/158 reads (18%) | called by muse, varscan2
- SLC16A10 | c.*24T>G | 3'UTR (SNP) | VAF 100/425 reads (24%) | called by muse, varscan2
- SLC34A3 | c.*82G>T | 3'UTR (SNP) | VAF 64/167 reads (38%) | called by muse, varscan2
- SSPOP | n.11698C>T | RNA (SNP) | VAF 95/598 reads (16%) | catalogued as rs766270308, COSV65129888; called by muse, varscan2
- TLE5 | c.235-44G>A | Intron (SNP) | VAF 26/168 reads (15%) | called by muse, varscan2
- TRPA1 | c.1530-40G>C | Intron (SNP) | VAF 138/742 reads (19%) | called by muse, varscan2
- ZSCAN32 | c.695-444G>A | Intron (SNP) | VAF 78/386 reads (20%) | called by muse, varscan2
